Gene-level copy-number profile of tumor specimen TCGA-A7-A13G-01A from TCGA case TCGA-A7-A13G, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.3 years (28,969 days).
Specimen TCGA-A7-A13G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.df947eb4-659d-46a6-95e1-fcc0d471a17c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A13G-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/406ffa1b-608b-49b1-b738-1ff9fb5b9853

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,103; copy number 2: 51,653; copy number 3: 1,642; copy number 5: 3,134; copy number 6: 192; copy number 7: 87; copy number 8: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A13G-01A-11D-A13J-01): tumor purity 0.86, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,416 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr7:13,339,201–13,365,049, 1 gene, copy number 7 (within-gene range 1–7): AC011287.2.
- chr7:14,985,378–23,564,261, 120 genes, copy number 6–8 (broad region; genes not listed).
- chr7:25,118,656–26,647,305, 31 genes, copy number 5–6: CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, AC004129.3, U3, TSEN15P3, AC003985.1, AC005100.1, AC005100.2, AC091705.1, AC005165.1, AC005165.2, AC005165.3, AC018706.1, AC010719.1, MIR148A, NFE2L3, HNRNPA2B1, CBX3, AC010677.2, AC010677.1, SNX10, AC004540.2, AC004540.1, KIAA0087, AC004947.2, AC004947.1, AC004947.3, LINC02860.
- chr7:39,888,375–57,837,046, 362 genes, copy number 5–6 (broad region; genes not listed).
- chr7:63,209,219–74,760,692, 298 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,103. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
